Gene-level copy-number profile of tumor specimen TCGA-AX-A1CP-01A from TCGA case TCGA-AX-A1CP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 84.2 years (30,737 days).
Specimen TCGA-AX-A1CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.65ba21c9-2627-4bcb-b4c0-9d39ce80462f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1CP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccdd2f3b-eb4b-4c73-9f3d-bf2ef13abca9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1; copy number 2: 9,982; copy number 3: 573; copy number 4: 45,887; copy number 5: 101; copy number 6: 1,767; copy number 7: 35; copy number 8: 107; copy number 9: 1,184; copy number 13: 36; copy number 16: 90; copy number 17: 21; copy number 25: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AX-A1CP-01): tumor purity 0.68, ploidy 1.92, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:34,118,347–34,579,369, 15 genes: AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,345 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,713,877–36,180,849, 16 genes, copy number 17: C1orf216, CLSPN, AL354864.1, AGO4, AGO1, CFAP97P1, AL139286.2, AL139286.1, AGO3, AL138787.2, AL138787.1, TEKT2, ADPRS, COL8A2, TRAPPC3, MAP7D1.
- chr1:39,838,110–45,340,893, 195 genes, copy number 9–16 (broad region; genes not listed).
- chr3:140,865,075–198,222,513, 1,003 genes, copy number 9–17 (broad region; genes not listed).
- chr17:39,210,541–39,747,291, 19 genes, copy number 9–25: STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr19:16,712,317–18,671,721, 112 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
